Somatic mutation profile of tumor specimen MP2PRT-PATCXJ-TMP1-A (aliquot MP2PRT-PATCXJ-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATCXJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 2.3 years (842 days).
Specimen MP2PRT-PATCXJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ec0ea4e-468b-4642-bc72-9a5b41877aad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCXJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCXJ-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/025f080f-f9c3-4070-98b0-0191222d109a

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 1, Frame Shift Ins 1, Silent 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO15 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 18/568 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs966703084; called by muse, mutect2
- IGFBPL1 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs142338613; called by muse, mutect2
- LOXL3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 18/594 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1474992303; called by muse, mutect2
- SLC25A37 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 53/435 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.837); catalogued as COSV51563681; called by muse, mutect2, varscan2
- ADAM15 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- ARID5B | c.37_38insTCCC p.C13Ffs*19 | Frame Shift Ins (INS) | VAF 68/426 reads (16%) | called by mutect2, pindel*, varscan2
- DPYSL2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 17/542 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.414); called by muse, mutect2
- GRB14 | c.935A>G p.K312R | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714683 del CTC | Missense Mutation (DEL) | VAF 16/48 reads (33%) | called by pindel*, varscan2
- PDZD4 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 73/428 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PI16 | c.1301T>A p.V434E | Missense Mutation (SNP) | VAF 161/425 reads (38%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51A7 | c.609T>C p.A203= | Silent (SNP) | VAF 28/520 reads (5%) | called by muse, mutect2
- IGHV1-58 | chr14:106627248 ins TC | 5'Flank (INS) | VAF 67/178 reads (38%) | called by pindel, varscan2
- IGHV5-51 | chr14:106578743 ins TCTCCCCTGATC | 3'Flank (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel
- RIMS1 | c.1679-20568C>T | Intron (SNP) | VAF 21/337 reads (6%) | called by muse, mutect2
